HCMI case HCM-STAN-0777-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8ee05a9d-2373-4598-afec-a42ed3be4082

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1951; Vital status: Dead; Days to death: 652 days (1.8 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C25.0; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Classification of tumor: primary; Age at diagnosis: 68.0 years (24,820 days); AJCC staging edition: 8th; AJCC clinical stage: Stage III; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Prior treatment: Yes.
   Pathology details: Peripancreatic lymph nodes positive: 1-3; Peripancreatic lymph nodes tested: 18.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 30 days.
   Treatment given: Treatment type: Stereotactic Radiosurgery; Treatment intent type: Neoadjuvant; Days to treatment start: 150 days.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 230 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Gemcitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 350 days; Days to treatment end: 400 days (1.1 years).
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C77.9; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 69.5 years (25,392 days); Days to diagnosis: 572 days (1.6 years).
   Pathology details: Peripancreatic lymph nodes positive: 1-3; Peripancreatic lymph nodes tested: 18.

Follow-up (2 entries)
- Days to follow up: 652 days (1.8 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 572.

Molecular and laboratory tests
- CDKN2A mutation, nos: Negative.
- CEA: 4 ng/mL; Blood test normal range upper: 5.
- KRAS substitution: Positive; Amino-acid change: p.Gly12Asp.
- SMAD4 (IHC): Negative.
- TP53 substitution: Positive; Amino-acid change: R175H.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 78 kg; Height: 177 cm; BMI: 25.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Alcohol intensity: Occasional Drinker; Alcohol days per week: 7.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample HCM-STAN-0777-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-STAN-0777-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
- Sample HCM-STAN-0777-C25-85S: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
